Somatic mutation profile of tumor specimen BA3351D (aliquot aq-BA3351D) from BEATAML1.0 case 2623, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute promyelocytic leukaemia, PML-RAR-alpha; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.1 years (26,345 days).
Specimen BA3351D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f0ab82f-8c49-46f4-afa2-376053d89199.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3440D (Solid Tissue Normal), aliquot aq-BA3440D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72f6a73c-7d25-408f-bf8f-f0c6388464bd

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTMR7 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs866092642; called by muse, mutect2
- NPAP1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.101); catalogued as rs759520625, COSV100274550; called by muse, mutect2, varscan2
- MUC16 | c.2494T>C p.S832P | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.455); called by muse, mutect2
- PRAMEF4 | c.990G>C p.L330= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs1236104503; called by mutect2, varscan2
